Gene-level copy-number profile of specimen HCM-CSHL-0246-C19-85A from HCMI case HCM-CSHL-0246-C19, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: GX; Age at diagnosis: 55.9 years (20,434 days).
Specimen HCM-CSHL-0246-C19-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4353961f-419c-4faa-abc5-78dc5e4c436c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0246-C19-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/5bf0fc15-02e6-468b-9b73-cf345c0de444

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 457; copy number 1: 4,385; copy number 2: 32,831; copy number 3: 14,047; copy number 4: 6,195; copy number 5: 755; copy number 6: 28; copy number 7: 99; copy number 8: 105; copy number 21: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 988 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–11,365,636, 185 genes, copy number 5 (broad region; genes not listed).
- chr7:5,190,196–30,993,254, 433 genes, copy number 5 (broad region; genes not listed).
- chr18:45,034–15,330,282, 367 genes, copy number 5–8 (broad region; genes not listed).
- chr19:27,638,483–27,646,483, 2 genes, copy number 5: ERVK-28, AC112702.1.
- chr21:8,857,260–8,880,976, 1 gene, copy number 21: CR381670.1.

Autosomal genes at a single copy (total copy number 1): 1,986. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
